Surgical pathology report (de-identified scan), TCGA case TCGA-F9-A97G, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Asterand, specimen TCGA-F9-A97G-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Renal tumor is located in a pole, moderately-margin, soft, solid, or yellow, gray surface with 4x4x3.5cm in size.

Microscopic Description: Tumor is high density and is composed of trabeculae or elongated tubules or papillary, back to back, variability in shape and size, lined by moderately stratified cylindrical or cuboidal cells. Nuclei are irregular large, hyperchromatic with prominent nucleoli. Mitoses are present. Cytoplasm are moderate, eosinophilic or clear. Tumor invades into capsule.

Diagnosis Details: Renal cell carcinoma, papillary type

ICD-O-3

Comments:

Carcinoma, papillary renal
cell 8260/3

Formatted Path Reports: KIDNEY TISSUE CHECKLIST

Specimen type: Radical nephrectomy

Site ① Kidney NOS C64.9
4/5/14

Tumor site: Kidney

Tumor size: 4 x 4 x 3.5 cm

Focality: Not specified

Histologic type: Renal cell carcinoma, papillary

Histologic grade: Moderately differentiated

Tumor extent: Extension to perinephric tissues

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor invades capsule, left

Comments: None

Source: NCI Genomic Data Commons file 7b0570cf-921d-4f4d-9965-0399d7aa6380 (TCGA-F9-A97G.9A8836F2-6D40-48B9-AB0B-1761AFA16EC7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).